Somatic mutation profile of tumor specimen TCGA-IQ-7631-01A (aliquot TCGA-IQ-7631-01A-11D-2078-08) from TCGA case TCGA-IQ-7631, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 60.6 years (22,151 days).
Specimen TCGA-IQ-7631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4a4e22-81fa-4c52-93ad-05c347b75869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-7631-10A (Blood Derived Normal), aliquot TCGA-IQ-7631-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/918f2416-fc7f-489c-81e2-1718ad0ec7d0

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 12, Nonsense Mutation 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMTA1 | c.4921C>T p.R1641* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as rs1057523792, COSV100348375, COSV100348424; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM10 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs761056936, COSV53054864; called by muse, mutect2, varscan2
- CREBBP | c.2105G>C p.R702T | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99269575; called by muse, mutect2, varscan2
- DRC7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs201048078, COSV61053152; called by muse, mutect2, varscan2
- DYRK3 | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV100895664; called by muse, mutect2, varscan2
- FAM47A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764123221, COSV60495125; called by muse, varscan2
- FAM47A | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as rs756542163, COSV100649835, COSV60493789; called by muse, varscan2
- GRK5 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV100962999; called by muse, mutect2, varscan2
- IGDCC4 | c.2242G>T p.G748* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100732829, COSV100732931; called by muse, mutect2
- MED12 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs766598254, COSV61338733; called by muse, mutect2
- MYH13 | c.5731G>A p.A1911T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs572120351, COSV99353533; called by muse, mutect2, varscan2
- OBSL1 | c.1091T>G p.V364G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99216674; called by muse, mutect2, varscan2
- PLAU | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs747051640, COSV65641726; called by muse, mutect2, varscan2
- SALL3 | c.3007C>T p.R1003W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs761366107, COSV73306124; called by muse, mutect2, varscan2
- SERPINE1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs760569885, COSV56169742; called by muse, mutect2, varscan2
- SOS1 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101216817; called by muse, mutect2, varscan2
- TENM1 | c.5276C>T p.S1759L | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100948718, COSV64435929; called by muse, mutect2, varscan2
- TENM1 | c.4253A>T p.K1418M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100949757; called by muse, mutect2, varscan2
- TRRAP | c.4874G>A p.R1625H (on ENST00000359863 / NM_001244580.1; = p.R1607H on NM_003496.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs3735363, COSV62840100; called by muse, mutect2, varscan2
- TRIL | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2
- USP9X | c.7320_7322del p.N2441del | In Frame Del (DEL) | VAF 34/88 reads (39%) | called by pindel, varscan2
- CNTNAP2 | c.444C>T p.H148= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs750661428, COSV62143240, COSV62147854; called by muse, mutect2, varscan2
- DLC1 | c.3627C>T p.S1209= (on ENST00000276297 / NM_001348081.2; = p.S772= on NM_006094.5) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs142586910; called by muse, mutect2, varscan2
- DQX1 | c.1776G>A p.Q592= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV99283603; called by muse, mutect2, varscan2
- FCAR | c.273C>T p.D91= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs767472780, COSV100629049; called by muse, mutect2, varscan2
- GFPT2 | c.57C>A p.I19= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99517579; called by muse, mutect2, varscan2
- KIAA1522 | c.1095C>T p.T365= (on ENST00000373480 / NM_001198972.2; = p.T424= on NM_020888.3) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99614487; called by muse, mutect2, varscan2
- MROH6 | c.1137G>A p.T379= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs368637582, COSV99434668; called by muse, mutect2, varscan2
- SKIV2L | c.1341C>T p.H447= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs771281472, COSV64812058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAP47 | c.1362C>T p.D454= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs766365494, COSV100248071; called by muse, mutect2, varscan2
- SPATA17 | c.783G>A p.T261= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs139943258, COSV65125406; called by muse, mutect2, varscan2
- SPIN1 | c.15C>T p.F5= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs201369257; called by muse, mutect2, varscan2
- ZNF862 | c.723A>C p.I241= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99783433; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185107C>T | Intron (SNP) | VAF 47/174 reads (27%) | catalogued as rs757066841, COSV100299348, COSV60946343; called by muse, mutect2, varscan2
